MMRF case MMRF_2039 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/34621984-f804-4060-935e-887814ebda45

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Dead; Days to death: 475 days (1.3 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.4 years (25,715 days); ISS stage: III; Days to last known disease status: 475 days (1.3 years); Days to last follow up: 475 days (1.3 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 197 days.
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 154 days; Days to treatment end: 280 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 312 days; Days to treatment end: 473 days (1.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 312 days; Days to treatment end: 475 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 386 days (1.1 years); Days to treatment end: 473 days (1.3 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 475.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 1.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24016 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 21.6 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 12.6 µg/mL; Lactate Dehydrogenase 4.62 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.75 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 380 µmol/L; Blood Urea Nitrogen 52.1 mmol/L; Calcium 2.05 mmol/L; Albumin 32 g/L; Total Protein 7.3 g/dL; Glucose 7.32 mmol/L.
- Day 95: M Protein 0.36 g/dL; Immunoglobulin G 4.98 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.5 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 5.16 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 61.9 µmol/L; Total Protein 6 g/dL; Glucose 5.23 mmol/L.
- Day 169 (ECOG 1): M Protein 0.46 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 197 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.5 mg/dL; Immunoglobulin G 6.48 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.35 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 303 ×10⁹/L; Creatinine 69 µmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.2 g/dL; Glucose 5.28 mmol/L.
- Day 290 (ECOG 1): M Protein 1.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1050 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.8 mg/dL; Immunoglobulin G 23.9 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 29.8 µg/mL; Hemoglobin 5.83 mmol/L; Leukocytes 5.62 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 216 µmol/L; Calcium 1.95 mmol/L; Total Protein 7.5 g/dL; Glucose 6.88 mmol/L.
- Day 386 (ECOG 1): M Protein 1.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1300 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.07 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 23 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 6.62 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 326 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 4.13 mmol/L.

Other clinical attributes
- Day 1: Weight: 70 kg; Height: 170 cm.

Biospecimens (3 samples)
- Sample MMRF_2039_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2039_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_2039_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 290 days.
